Somatic mutation profile of tumor specimen 0DSWZA from CCDI case PBCIWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DSWZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54f839fc-d634-4ed0-b939-1b73b2ba03b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWZ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d274071b-695c-4d83-a911-2ef351b726d7

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK12 | c.2603A>G p.N868S | Missense Mutation (SNP) | VAF 156/565 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR18 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 86/612 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KBTBD4 | c.883_891dup p.P295_R297dup | In Frame Ins (INS) | VAF 140/378 reads (37%) | called by mutect2, varscan2
- ZNF92 | c.1081A>G p.I361V (on ENST00000328747 / NM_152626.4; = p.I292V on NM_007139.4) | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.034); called by muse, mutect2
- DZIP1L | c.819A>G p.L273= | Silent (SNP) | VAF 91/826 reads (11%) | called by muse, mutect2, varscan2
